CCDI case PBCHLH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4e64038d-8319-4610-8bc7-1f8a7a27f731

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.7 years (1,700 days).

Biospecimens (3 samples)
- Sample 0DS0ZE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DS0ZM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS0ZZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
